Somatic mutation profile of tumor specimen TCGA-G9-6329-01A (aliquot TCGA-G9-6329-01A-13D-1961-08) from TCGA case TCGA-G9-6329, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 67.9 years (24,797 days).
Specimen TCGA-G9-6329-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a2f7bc9-ef9f-4dac-90d1-9e3f8f4b6c08.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G9-6329-10A (Blood Derived Normal), aliquot TCGA-G9-6329-10A-01D-1961-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0f32a21-a8e3-4ef8-9571-519d9bfd50ad

The open-access MAF lists 23 somatic variants for this specimen: 17 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 14, Silent 6, Nonsense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD8 | c.700A>G p.M234V | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1459777077, COSV53113073; called by muse, mutect2
- ATIC | c.104G>A p.G35E | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52694194; called by muse, mutect2, varscan2
- COL12A1 | c.1682C>T p.A561V | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1344964508, COSV59400612; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A1 | c.2080G>A p.G694R | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV65670431; called by muse, mutect2, varscan2
- ESF1 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.003); catalogued as rs771646381, COSV52522462; called by muse, mutect2, varscan2
- F12 | c.1333C>T p.R445C | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV53692106; called by muse, mutect2
- ITPRID1 | c.980A>G p.Y327C | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.517); catalogued as COSV60077980; called by muse, mutect2, varscan2
- NMUR2 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs368505984, COSV54922171; called by muse, mutect2, varscan2
- NUP50 | c.824A>G p.K275R | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as rs564086226, COSV61661294; called by muse, varscan2
- PKD2L1 | c.2317C>T p.Q773* | Nonsense Mutation (SNP) | VAF 18/121 reads (15%) | catalogued as COSV58397039; called by muse, mutect2, varscan2
- PRPF19 | c.1084G>T p.G362* | Nonsense Mutation (SNP) | VAF 9/71 reads (13%) | catalogued as COSV57128552; called by muse, mutect2, varscan2
- RAB3GAP1 | c.440T>G p.L147R | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV51484887; called by muse, mutect2, varscan2
- TRIO | c.8413G>A p.G2805S | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1252197672, COSV59991240; called by muse, mutect2
- WDR17 | c.1430A>G p.E477G | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54578133; called by muse, mutect2
- WIPI1 | c.1026T>G p.N342K | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV50930656; called by muse, mutect2
- ZBTB11 | c.1190C>G p.S397* | Nonsense Mutation (SNP) | VAF 13/124 reads (10%) | catalogued as COSV57245902; called by muse, mutect2, varscan2
- ZNF675 | c.689G>A p.C230Y | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); catalogued as rs780857344, COSV63096596; called by muse, mutect2, varscan2
- CBX4 | c.342G>A p.K114= | Silent (SNP) | VAF 18/158 reads (11%) | catalogued as COSV53966314; called by muse, mutect2, varscan2
- CCAR2 | c.1227G>A p.Q409= | Silent (SNP) | VAF 33/183 reads (18%) | catalogued as COSV52385449, COSV99374328; called by muse, mutect2, varscan2
- EDNRA | c.352C>T p.L118= | Silent (SNP) | VAF 15/104 reads (14%) | catalogued as COSV60098821; called by muse, mutect2, varscan2
- ERN2 | c.603G>A p.L201= | Silent (SNP) | VAF 5/62 reads (8%) | catalogued as COSV56835460; called by muse, mutect2
- MDN1 | c.6726C>T p.D2242= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as COSV65524815; called by muse, mutect2, varscan2
- THSD7B | c.705G>T p.G235= | Silent (SNP) | VAF 33/309 reads (11%) | catalogued as COSV55710250; called by muse, mutect2, varscan2
